Somatic mutation profile of tumor specimen TCGA-BR-8678-01A (aliquot TCGA-BR-8678-01A-11D-2394-08) from TCGA case TCGA-BR-8678, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 76.8 years (28,037 days).
Specimen TCGA-BR-8678-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f34c01fc-dce5-4f4e-85a0-d7525fc9cb17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8678-10A (Blood Derived Normal), aliquot TCGA-BR-8678-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/002b91da-89f0-4641-b694-6cc129785198

The open-access MAF lists 120 somatic variants for this specimen: 94 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 25, Nonsense Mutation 7, Frame Shift Del 5, Intron 1, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.3765T>A p.D1255E | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV52503076; called by muse, mutect2, varscan2
- CACNA2D4 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373696894; called by muse, mutect2, varscan2
- CBLL2 | c.131A>C p.N44T | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV60368420; called by muse, mutect2
- CCT8L2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.069); catalogued as rs573220545, COSV63461652, COSV63464157; called by muse, mutect2, varscan2
- CD93 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs867528103, COSV55663356, COSV55666402; called by mutect2, varscan2
- CFAP61 | c.2408C>A p.T803K | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as rs780255308, COSV55619741, COSV55624296; called by muse, mutect2, varscan2
- CHKB | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs758217425, COSV100376885, COSV56415895; called by muse, mutect2
- CIBAR2 | c.309G>T p.Q103H | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT tolerated (0.61); PolyPhen benign (0.076); catalogued as COSV101608269, COSV73320534; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 29/315 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760621032, COSV59974007; called by muse, mutect2
- CYP20A1 | c.289T>G p.S97A | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs374531910, COSV61909023; called by muse, mutect2, varscan2
- DCLK1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs368906217, COSV55186132; called by muse, mutect2, varscan2
- DLEU7 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1280474400, COSV68546525; called by muse, mutect2, varscan2
- DNAH11 | c.4009C>T p.R1337* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs1447609804, COSV60940698; called by muse, mutect2, varscan2
- DUXA | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs780439658, COSV73729496; called by muse, mutect2, varscan2
- EFCAB2 | c.715G>T p.V239F (on ENST00000366522; = p.V103F on NM_032328.3) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100833989; called by muse, mutect2, varscan2
- ERCC4 | c.2548G>C p.D850H | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61310737; called by muse, mutect2, varscan2
- ERCC6L2 | c.1726G>A p.V576I | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV56628302; called by muse, mutect2, varscan2
- EVX2 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as rs750266838, COSV57962518; called by muse, mutect2, varscan2
- FBLN7 | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374648225; called by muse, mutect2, varscan2
- FBXW7 | c.1210A>G p.K404E (on ENST00000281708 / NM_001349798.2; = p.K324E on NM_018315.5) | Missense Mutation (SNP) | VAF 76/94 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55894686; called by muse, mutect2, varscan2
- FCRL6 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV58940001; called by muse, mutect2, varscan2
- FZD4 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV72294211; called by muse, mutect2, varscan2
- GJB7 | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.398); catalogued as COSV51528769; called by muse, mutect2, varscan2
- GLG1 | c.810G>T p.L270F | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52663999; called by muse, mutect2
- GOLGA3 | c.3856-1G>C p.X1286_splice | Splice Site (SNP) | VAF 61/106 reads (58%) | catalogued as COSV52625813; called by muse, mutect2, varscan2
- GOLGB1 | c.9285G>T p.K3095N | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV61461918, COSV61468660; called by muse, mutect2, varscan2
- GOLGB1 | c.5867C>G p.S1956C | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV61461928; called by muse, mutect2, varscan2
- GPAT4 | c.429G>A p.W143* | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | catalogued as COSV67840233, COSV67840672; called by muse, mutect2, varscan2
- GSTT2 | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1420434774, COSV53159878; called by mutect2, varscan2
- H2AC4 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52517894; called by muse, mutect2, varscan2
- HECTD4 | c.6443G>A p.R2148H | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200891866; called by muse, mutect2, varscan2
- KCNA6 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs778808157, COSV54974074; called by muse, mutect2, varscan2
- KCTD20 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 108/236 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs767251203, COSV54802205; called by muse, mutect2, varscan2
- KDM4C | c.2762C>T p.T921I | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.291); catalogued as rs753394685, COSV67183737; called by muse, mutect2, varscan2
- KIF26B | c.2749G>T p.E917* | Nonsense Mutation (SNP) | VAF 23/33 reads (70%) | catalogued as COSV63636960, COSV63641137; called by muse, mutect2, varscan2
- KRBA1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV55440023; called by muse, mutect2, varscan2
- LRP1B | c.13141A>G p.N4381D | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV67187758; called by muse, mutect2, varscan2
- LRP1B | c.12659C>G p.T4220S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV67187761; called by muse, mutect2, varscan2
- LRP1B | c.5915A>T p.H1972L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV67187765; called by muse, mutect2
- LRP1B | c.1208del p.N403Ifs*17 | Frame Shift Del (DEL) | VAF 46/136 reads (34%) | catalogued as COSV67205391; called by mutect2, pindel, varscan2
- LTN1 | c.461C>G p.A154G | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV63732988; called by muse, mutect2, varscan2
- MUC17 | c.5756C>T p.S1919L | Missense Mutation (SNP) | VAF 71/323 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV60280473; called by muse, mutect2, varscan2
- NAV2 | c.6562G>A p.A2188T (on ENST00000396087 / NM_001244963.2; = p.A2129T on NM_145117.5) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs757815258, COSV60656576; called by muse, mutect2, varscan2
- NETO1 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as rs1267926349, COSV55001858, COSV55012005; called by muse, mutect2, varscan2
- NPHP3 | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 14/145 reads (10%) | catalogued as COSV58628114; called by muse, mutect2, varscan2
- NPR2 | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1319830472, COSV61039717; called by muse, mutect2, varscan2
- NSMF | c.974T>C p.L325P (on ENST00000371475 / NM_001130969.3; = p.L323P on NM_015537.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55809674; called by mutect2, varscan2
- NUP205 | c.2950A>G p.R984G | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV53655191; called by muse, mutect2, varscan2
- OR5AS1 | c.181T>G p.Y61D | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV57980841; called by muse, mutect2, varscan2
- OR5R1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as rs1406679896, COSV56571502; called by muse, mutect2
- OR8I2 | c.409T>C p.S137P | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV56166642; called by muse, mutect2, varscan2
- PABPC5 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57039213; called by muse, mutect2, varscan2
- PANX3 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as rs372236130; called by muse, mutect2, varscan2
- PARD6B | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773565570, COSV65404092; called by muse, mutect2, varscan2
- PCDH9 | c.2932G>A p.D978N | Missense Mutation (SNP) | VAF 124/196 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs755751696, COSV60529839; called by muse, mutect2, varscan2
- PKP3 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58986001; called by muse, mutect2, varscan2
- PPP1R3A | c.1403A>C p.K468T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as COSV52876670; called by muse, mutect2, varscan2
- PPP1R42 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61206642; called by muse, mutect2, varscan2
- PRSS38 | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs761686830, COSV64539672; called by muse, mutect2, varscan2
- PZP | c.1791C>A p.D597E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54354688; called by muse, mutect2, varscan2
- RAD18 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53749148; called by muse, mutect2, varscan2
- RAE1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64797745; called by muse, mutect2, varscan2
- RGL2 | c.1892C>A p.A631D | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV65841952; called by muse, mutect2, varscan2
- RHBG | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1409098664, COSV54801855; called by muse, mutect2, varscan2
- RPL10L | c.221A>T p.K74I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53558667; called by muse, mutect2, varscan2
- SCN10A | c.4343A>C p.K1448T | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV71860120; called by muse, mutect2
- SF3B1 | c.3723T>G p.I1241M | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV59207043; called by muse, varscan2
- SMC6 | c.3143T>G p.L1048R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61171511; called by muse, mutect2, varscan2
- SMCHD1 | c.4378T>C p.Y1460H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV55251875; called by muse, mutect2, varscan2
- SPP2 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.382); catalogued as COSV51444456; called by muse, mutect2, varscan2
- SPRED1 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV54434404; called by muse, mutect2, varscan2
- SPTBN5 | c.7636G>A p.D2546N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs537948359, COSV58016529; called by muse, mutect2, varscan2
- TAOK2 | c.2335G>T p.G779C | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV54233199; called by muse, mutect2, varscan2
- TENM4 | c.6479G>A p.R2160H | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs144957611, COSV53609764; called by muse, mutect2, varscan2
- TFAP2D | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as rs143299031; called by muse, mutect2, varscan2
- TP53 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 47/72 reads (65%) | catalogued as COSV52677652, COSV52734727, COSV52787469, COSV53371041; called by muse, mutect2, varscan2
- TP53TG5 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1419680732, COSV65576953; called by muse, mutect2
- TRHDE | c.2228G>T p.R743I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.9); catalogued as COSV99672940; called by muse, mutect2, varscan2
- TTC26 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV58269591; called by muse, mutect2, varscan2
- TTC27 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as rs769072122, COSV58648954; called by muse, mutect2, varscan2
- TTN | c.51376G>T p.V17126L (on ENST00000591111; = p.V9702L on NM_003319.4) | Missense Mutation (SNP) | VAF 125/290 reads (43%) | PolyPhen benign (0.053); catalogued as COSV59895907; called by muse, mutect2, varscan2
- ULK4 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 41/84 reads (49%) | catalogued as COSV57199343; called by muse, mutect2, varscan2
- USP9X | c.5080G>A p.V1694M | Missense Mutation (SNP) | VAF 83/88 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1313735538, COSV61066217; called by muse, mutect2, varscan2
- ZFYVE26 | c.5402C>A p.A1801E | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100720417; called by muse, varscan2
- ZNF462 | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs746021945, COSV52930720; called by muse, mutect2, varscan2
- ZNF622 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58073460; called by muse, mutect2, varscan2
- AFF1 | c.1107_1118del p.P370_A373del | In Frame Del (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- AKAP11 | c.982dup p.S328Kfs*7 | Frame Shift Ins (INS) | VAF 17/143 reads (12%) | called by mutect2, pindel, varscan2
- BBS5 | c.91del p.I31Lfs*4 | Frame Shift Del (DEL) | VAF 31/210 reads (15%) | called by mutect2, pindel, varscan2
- IGHE | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.94); PolyPhen benign (0.015); called by muse, mutect2
- OR2L8 | c.113_128del p.L38Pfs*2 | Frame Shift Del (DEL) | VAF 40/388 reads (10%) | called by mutect2, pindel
- PRR5L | c.460del p.I154Sfs*12 | Frame Shift Del (DEL) | VAF 37/59 reads (63%) | called by mutect2, pindel, varscan2
- SATB1 | c.631del p.L211Ffs*5 | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | called by mutect2, pindel, varscan2
- ZNF596 | c.1097A>T p.H366L | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2
- ADRA1B | c.936C>A p.I312= | Silent (SNP) | VAF 59/81 reads (73%) | catalogued as COSV60700545; called by muse, mutect2, varscan2
- APOA4 | c.804G>A p.A268= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs1322409487, COSV63360032; called by muse, mutect2, varscan2
- BCL2L12 | c.519C>T p.D173= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV55862324; called by muse, mutect2, varscan2
- BRINP3 | c.2244G>A p.A748= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs562180986, COSV66514032; called by muse, mutect2, varscan2
- CA2 | c.396A>G p.K132= | Silent (SNP) | VAF 85/149 reads (57%) | catalogued as COSV53405791; called by muse, mutect2, varscan2
- COG7 | c.1668A>G p.K556= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV56149171; called by muse, mutect2
- CTR9 | c.1125C>T p.Y375= | Silent (SNP) | VAF 80/110 reads (73%) | catalogued as rs756358525, COSV63727845; called by muse, mutect2, varscan2
- DNAH11 | c.1693T>C p.L565= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV60940682; called by muse, mutect2, varscan2
- EDAR | c.1134C>T p.A378= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs1286827572, COSV51500045; called by muse, mutect2, varscan2
- FASTKD2 | c.1935T>C p.C645= | Silent (SNP) | VAF 64/183 reads (35%) | catalogued as COSV52697445; called by muse, mutect2, varscan2
- HINFP | c.420C>T p.F140= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs200463414, COSV63431644; called by muse, mutect2, varscan2
- LGI1 | c.1392G>A p.S464= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs148804268; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MEI1 | c.3711C>A p.T1237= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV55387529; called by muse, mutect2, varscan2
- NCAM2 | c.2094T>A p.G698= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV53057245; called by muse, varscan2
- NEURL4 | c.513C>T p.L171= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV59756337; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1251T>C p.I417= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV52964484; called by muse, mutect2, varscan2
- SCAF1 | c.3216C>T p.D1072= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs752209930, COSV62182379; called by muse, mutect2
- SLC8A1 | c.2520C>T p.F840= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs767425092, COSV60471278, COSV60497831; called by muse, mutect2, varscan2
- SPATA31D1 | c.720C>A p.P240= | Silent (SNP) | VAF 34/382 reads (9%) | catalogued as COSV61192894; called by muse, mutect2
- TBX22 | c.1515C>A p.G505= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV64785006; called by muse, mutect2, varscan2
- TTN | c.2916G>A p.P972= (on ENST00000591111; = p.P926= on NM_003319.4) | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs757569345, COSV59895929; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- U2AF2 | c.414C>T p.P138= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as rs201509109, COSV100454373; called by muse, mutect2, varscan2
- UBE3B | c.87G>A p.R29= | Silent (SNP) | VAF 97/161 reads (60%) | catalogued as rs375632180; called by muse, mutect2, varscan2
- UNC5CL | c.1200C>A p.S400= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99771027; called by muse, mutect2
- USP49 | c.135C>T p.A45= | Silent (SNP) | VAF 18/167 reads (11%) | catalogued as COSV51894839; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1618A>T | Intron (SNP) | VAF 52/78 reads (67%) | catalogued as COSV100678860; called by muse, mutect2, varscan2
